Somatic mutation profile of tumor specimen ALCH-B1YS-TTP1-A (aliquot ALCH-B1YS-TTP1-A-2-0-D-A76I-36) from ALCHEMIST case ALCH-B1YS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.2 years (21,620 days).
Specimen ALCH-B1YS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02bddd87-404f-490d-b15c-77fdadc5b01d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YS-NB1-A (Blood Derived Normal), aliquot ALCH-B1YS-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/215bc8cb-da67-4f7b-94dc-5ec8cc155905

The open-access MAF lists 446 somatic variants for this specimen: 304 protein-altering or splice-affecting, 90 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 90, Intron 27, Nonsense Mutation 22, Splice Site 8, 5'UTR 8, RNA 7, Frame Shift Del 7, Splice Region 4, 3'UTR 4, 3'Flank 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OTC | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 45/140 reads (32%) | catalogued as rs72558466, CM930533, COSV99234243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PSMD12 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as rs1114167442, COSV62065273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 38/129 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1334238002, COSV53976319; called by muse, mutect2, varscan2
- ANKRD28 | c.2721G>T p.L907F | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs775161986; called by muse, mutect2, varscan2
- ANKRD30B | c.2654A>G p.Q885R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1279281827; called by muse, mutect2, varscan2
- ANKRD46 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1344346847; called by muse, mutect2, varscan2
- ANKS1B | c.1202C>A p.P401Q | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV61336347; called by muse, mutect2, varscan2
- APOB | c.9283C>A p.Q3095K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51935862; called by muse, mutect2, varscan2
- ATP6AP2 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs767631127, COSV101011576, COSV65797453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCHE | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100013035; called by muse, mutect2, varscan2
- BLK | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775270203, COSV99377768; called by muse, mutect2, varscan2
- BOD1L1 | c.8985G>T p.E2995D | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV50008041; called by muse, varscan2
- BPIFB6 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.033); catalogued as COSV62755553; called by muse, mutect2, varscan2
- CACNA1E | c.5244G>T p.W1748C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62401840; called by muse, mutect2, varscan2
- CACNA1S | c.2058G>A p.M686I | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.114); catalogued as rs1345391060; called by muse, mutect2, varscan2
- CD5L | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs977085925; called by muse, mutect2, varscan2
- CDH7 | c.1955G>A p.R652K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.294); catalogued as rs757266413; called by muse, mutect2, varscan2
- CEACAM20 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.572); catalogued as rs753815647; called by muse, varscan2
- CFAP47 | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.63); PolyPhen benign (0.248); catalogued as COSV99934934; called by muse, mutect2, varscan2
- CFH | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661393, COSV62778172; called by muse, mutect2, varscan2
- CHRM3 | c.618C>A p.F206L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.191); catalogued as rs778872727, COSV99699314; called by muse, mutect2, varscan2
- CIAO2A | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1033438183; called by muse, mutect2, varscan2
- CIP2A | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV55418613; called by muse, mutect2, varscan2
- CLIC2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1326420135, COSV58936128; called by muse, mutect2, varscan2
- CSMD3 | c.8060C>A p.P2687H (on ENST00000297405 / NM_001363185.1; = p.P2583H on NM_052900.3) | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52122249; called by muse, mutect2, varscan2
- CXorf65 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as rs1434530060, COSV52147769; called by muse, mutect2, varscan2
- DNAH9 | c.5045A>T p.H1682L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs747650923; called by muse, mutect2, varscan2
- DOCK4 | c.5168G>C p.C1723S | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV70243916; called by muse, varscan2
- DSCAM | c.3605C>T p.A1202V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV101259204; called by muse, mutect2, varscan2
- DSP | c.7219G>T p.D2407Y | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV65793959; called by muse, mutect2, varscan2
- EGFL6 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 44/159 reads (28%) | catalogued as COSV100789896, COSV100789950; called by muse, mutect2, varscan2
- ENPP5 | c.1103T>C p.M368T | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs774504999; called by muse, mutect2, varscan2
- EPHA5 | c.2267T>C p.M756T | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759540768; called by muse, mutect2, varscan2
- EPHA5 | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56630629, COSV56642319, COSV56642837; called by muse, mutect2, varscan2
- F2 | c.1407G>T p.K469N | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV61315277, COSV61317694; called by muse, mutect2
- FGF2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV52649399; called by muse, varscan2
- FZD2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867681109, COSV59528501; called by muse, mutect2, varscan2
- GCSAML | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63578833; called by muse, mutect2, varscan2
- HNF1B | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM145960; called by muse, mutect2, varscan2
- ID4 | c.*13A>G | Splice Region (SNP) | VAF 3/23 reads (13%) | catalogued as rs774615364; called by mutect2, varscan2
- IFI44L | c.953G>C p.C318S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374146000, COSV60726626; called by muse, mutect2, varscan2
- IL20RB | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs775235617, COSV59047229; called by muse, mutect2, varscan2
- JMJD1C | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs749556972; called by muse, mutect2, varscan2
- KIF24 | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV61456770; called by muse, varscan2
- LNX1 | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1198013870; called by muse, mutect2, varscan2
- LRP2 | c.10106G>C p.G3369A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV55575916; called by muse, mutect2, varscan2
- LRRC55 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs200093413; called by mutect2, varscan2
- LRRC8C | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs148090493, COSV64995434; called by muse, mutect2, varscan2
- LTBP4 | c.140C>G p.P47R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1420778683; called by muse, mutect2, varscan2
- LYST | c.8222G>A p.R2741Q | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs148018560; called by muse, mutect2, varscan2
- MAEL | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.098); catalogued as rs1170601488; called by muse, mutect2, varscan2
- MARS2 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs757093106; called by muse, mutect2, varscan2
- MDGA2 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 10/109 reads (9%) | catalogued as rs966820214, COSV62092848; called by muse, mutect2, varscan2
- MEIS1 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV104378937; called by muse, mutect2, varscan2
- MSH3 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 15/103 reads (15%) | catalogued as COSV54148903; called by muse, mutect2, varscan2
- MUC17 | c.5698A>T p.T1900S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.662); catalogued as rs778888418, COSV100072052; called by mutect2, varscan2
- MYCN | c.1180C>G p.R394G | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55261260; called by muse, mutect2, varscan2
- NEDD4 | c.3475C>T p.R1159* (on ENST00000508342 / NM_001284338.1; = p.R740* on NM_006154.4) | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as rs775266689, COSV59059066; called by muse, varscan2
- NLRP10 | c.1859del p.S620Lfs*12 | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | catalogued as COSV60780613; called by mutect2, pindel*, varscan2
- NLRP13 | c.3013A>T p.S1005C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV61621552; called by muse, mutect2, varscan2
- NRXN1 | c.466G>C p.G156R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV68007646, COSV68007760, COSV68010120; called by muse, mutect2, varscan2
- OR10G8 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV70908283; called by muse, mutect2, varscan2
- OR5AS1 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100546429; called by muse, mutect2, varscan2
- OR5M10 | c.737C>A p.T246K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs767694706; called by muse, mutect2, varscan2
- OR6N1 | c.175A>G p.M59V | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs772334526; called by muse, mutect2, varscan2
- OTOGL | c.4280-1G>T p.X1427_splice (on ENST00000547103; = p.X1418_splice on NM_173591.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV101509183; called by muse, mutect2, varscan2
- PCDHAC1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781857799, COSV53846278; called by muse, mutect2, varscan2
- PDZD9 | c.482G>T p.R161I (on ENST00000424898 / NM_001363519.1; = p.R101I on NM_173806.4) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as rs1567483648; called by muse, mutect2
- PIK3CA | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as rs1428379257, COSV55891134, COSV55893970; called by muse, mutect2
- PPP6R3 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55725738; called by muse, mutect2, varscan2
- PRAMEF2 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs779898048; called by muse, varscan2
- PTPRT | c.1967C>T p.S656F | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs146825584, COSV61961995; called by muse, mutect2, varscan2
- RBM46 | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1247945420, COSV99908057; called by muse, mutect2, varscan2
- RGL2 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1393666908; called by muse, mutect2, varscan2
- RNF213 | c.9799G>C p.V3267L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100301341; called by muse, mutect2, varscan2
- RTL9 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV71826492; called by mutect2, varscan2
- RTN2 | c.1127T>G p.I376S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1485014312; called by muse, mutect2, varscan2
- RYR2 | c.4560C>A p.F1520L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63707090; called by muse, mutect2, varscan2
- SBSN | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs755418538; called by muse, varscan2
- SHROOM2 | c.3973G>T p.G1325W | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768256757; called by muse, mutect2, varscan2
- SLFN14 | c.1995G>T p.E665D | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV70570159; called by muse, mutect2, varscan2
- SMYD3 | c.688G>A p.E230K (on ENST00000490107 / NM_001375962.1; = p.E171K on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs147009044, COSV63629740; called by muse, mutect2, varscan2
- SOX11 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.132); catalogued as rs573393747; called by muse, varscan2
- SPSB2 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as COSV51290491; called by muse, mutect2, varscan2
- STARD9 | c.5263G>A p.A1755T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs946020533; called by muse, mutect2, varscan2
- STK3 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV69221623; called by muse, varscan2
- STX12 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377420642; called by muse, mutect2, varscan2
- STYXL2 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs774975802, COSV54806377; called by muse, mutect2, varscan2
- SYBU | c.1712A>G p.N571S (on ENST00000276646 / NM_001099754.2; = p.N570S on NM_017786.6) | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1484933200; called by muse, mutect2, varscan2
- TAF1L | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339036354; called by muse, mutect2, varscan2
- TECTA | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 29/178 reads (16%) | catalogued as rs751352958, COSV50687793; called by muse, mutect2, varscan2
- THOC2 | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99833284; called by muse, mutect2, varscan2
- TMEM209 | c.1026G>A p.W342* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as rs773400478; called by muse, mutect2, varscan2
- TNN | c.1958G>T p.R653L | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs142549967; called by muse, mutect2, varscan2
- VRTN | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs779766385, COSV56440026; called by muse, mutect2, varscan2
- VRTN | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373225215, COSV56439428; called by muse, mutect2, varscan2
- WHRN | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as CM135923; called by muse, mutect2, varscan2
- XPNPEP3 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64028330; called by muse, mutect2, varscan2
- ZAN | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.245); catalogued as rs769810485, COSV61807537, COSV61816885; called by muse, mutect2, varscan2
- ZBED1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs753593988; called by muse, mutect2
- ZDBF2 | c.5105G>T p.S1702I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs1347785484; called by muse, mutect2, varscan2
- ZEB2 | c.1586C>A p.T529K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100357358; called by muse, mutect2, varscan2
- ZFHX4 | c.3633C>A p.F1211L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51499043; called by muse, mutect2, varscan2
- ZIC1 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | catalogued as rs1358185553, COSV51556993, COSV51557111; called by muse, mutect2, varscan2
- ZNF208 | c.2990G>T p.G997V | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777218538; called by muse, mutect2, varscan2
- ZNF431 | c.671G>T p.R224I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs759648697; called by muse, mutect2, varscan2
- ZNF583 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.971); catalogued as COSV52401917, COSV52404504; called by muse, mutect2, varscan2
- ZNF616 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765934151, COSV57509360; called by muse, mutect2, varscan2
- ZNF77 | c.703C>G p.H235D | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1336566613; called by muse, mutect2
- ZNF83 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV56528579; called by muse, mutect2, varscan2
- ACAN | c.5848A>T p.T1950S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ACKR3 | c.802T>A p.Y268N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADGRF5 | c.1634G>T p.C545F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGPAT4 | c.236del p.P79Rfs*37 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel
- AL592490.1 | c.1721T>G p.L574R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASCC3 | c.3610G>T p.A1204S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AUTS2 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AXDND1 | c.2315C>A p.A772E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- BRINP3 | c.2088G>T p.Q696H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CCDC158 | c.3172C>A p.P1058T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC158 | c.1504A>G p.T502A | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDA | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2
- CFAP61 | c.2464_2466delinsCC p.A822Pfs*2 | Frame Shift Del (DEL) | VAF 45/219 reads (21%) | called by pindel, varscan2*
- CHRNA6 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNTNAP4 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- COL20A1 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CPAMD8 | c.5041G>T p.V1681L (on ENST00000651564; = p.V1634L on NM_015692.5) | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- CR2 | c.17dup p.L7Afs*29 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- CYLC1 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- DAB1 | c.1613C>A p.T538K (on ENST00000371231; = p.T505K on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, varscan2
- DCAF8L1 | c.1556C>A p.T519N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDIAS | c.1925C>A p.P642Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DENND1B | c.1695G>T p.M565I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DHX38 | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLL4 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- DMBT1 | c.5055G>A p.M1685I (on ENST00000338354 / NM_001377530.1; = p.M928I on NM_004406.3) | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DMP1 | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAH8 | c.10934C>T p.S3645F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK2 | c.4197G>T p.K1399N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DROSHA | c.1990C>T p.L664F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DSP | c.5406G>T p.K1802N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, varscan2
- DYNLRB2 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ECE1 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- EXOC1 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FAM71F1 | c.373C>A p.H125N | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.107); called by muse, mutect2
- FANCL | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAP | c.534T>A p.D178E | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- FAT4 | c.6559G>T p.G2187* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- FCGR2A | c.112C>A p.P38T (on ENST00000271450 / NM_001136219.3; = p.P37T on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FGB | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FHAD1 | c.4184C>T p.T1395I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FHL3 | c.131A>T p.Q44L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FIBIN | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLG | c.4797C>A p.D1599E | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- FRMPD4 | c.744G>T p.M248I | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSIP2 | c.10718T>G p.I3573S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA3 | c.446C>A p.P149Q | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA6 | c.674-7_674-6insA | Splice Region (INS) | VAF 18/50 reads (36%) | called by mutect2, pindel*, varscan2
- GALNT10 | c.1640G>A p.W547* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- GIGYF1 | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPATCH3 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR157 | c.299T>A p.I100N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GRAMD1C | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HAS1 | c.1618C>A p.H540N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HEPACAM2 | c.572C>T p.T191I (on ENST00000394468 / NM_001039372.4; = p.T179I on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/327 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN2 | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- HOPX | c.75C>A p.D25E (on ENST00000317745; = p.D43E on NM_032495.6) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HOXD11 | c.851A>C p.E284A | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSH2D | c.508A>C p.K170Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by mutect2, varscan2
- HSPG2 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- IDI1 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHG3 | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- IGKV3D-7 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
- IKZF3 | c.593-2A>G p.X198_splice | Splice Site (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- ITGA8 | c.2051A>T p.Y684F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITLN1 | c.572C>A p.P191Q | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNB2 | c.2456C>A p.P819Q | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ2 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
- KDELR2 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KIAA0232 | c.4086G>A p.M1362I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2012 | c.282C>G p.C94W | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- KIF4A | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- KYAT3 | c.454-2A>T p.X152_splice | Splice Site (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- LCE2D | c.118T>C p.C40R | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- LGSN | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LMNA | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONRF1 | c.2147G>T p.R716M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- LOXHD1 | c.4000G>T p.D1334Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- LRRC66 | c.588A>T p.Q196H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.071); called by muse, varscan2
- LTBP2 | c.2108A>T p.K703I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- MAGEA8 | c.150dup p.E51* | Frame Shift Ins (INS) | VAF 23/44 reads (52%) | called by mutect2, pindel, varscan2
- MAGEB16 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- MAP3K4 | c.2225G>C p.G742A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- MAPK10 | c.827C>T p.P276L (on ENST00000359221 / NM_001351625.2; = p.P314L on NM_002753.5) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MC4R | c.695C>G p.T232S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- MECOM | c.1988C>T p.S663F (on ENST00000468789 / NM_001105078.4; = p.S851F on NM_004991.4) | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by muse, varscan2
- MGAM2 | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- MINPP1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.079); called by muse, varscan2
- MKI67 | c.6109A>G p.K2037E | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MLANA | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- MLH3 | c.2736C>A p.C912* | Nonsense Mutation (SNP) | VAF 29/135 reads (21%) | called by muse, mutect2, varscan2
- MMP15 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MNDA | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.173); called by muse, mutect2
- MROH1 | c.4774+1G>T p.X1592_splice | Splice Site (SNP) | VAF 48/74 reads (65%) | called by muse, mutect2, varscan2
- MSX1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- MUC16 | c.14804C>T p.S4935F | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- MYH3 | c.3940G>T p.E1314* | Nonsense Mutation (SNP) | VAF 82/215 reads (38%) | called by muse, mutect2, varscan2
- NACAD | c.2981C>A p.A994D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NADSYN1 | c.1964C>A p.P655H | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAP1L2 | c.1116T>A p.N372K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV3 | c.2516+1G>T p.X839_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- NCKAP5 | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- NPAS2 | c.1140+5G>T | Splice Region (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- NSUN5 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- OCA2 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- OR10AG1 | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by mutect2, varscan2
- OR10Q1 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR10Z1 | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR12D3 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2A25 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR2AK2 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- OR2B2 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR2F2 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4N5 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR52L1 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- OR5T3 | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- OR6B1 | c.57del p.S20Afs*2 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- OR6B2 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, varscan2
- OR8B2 | c.171_172del p.P58Nfs*12 | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | called by pindel, varscan2
- OTOGL | c.1651G>T p.V551L (on ENST00000547103; = p.V542L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, varscan2
- PAX4 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCSK5 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PDZD2 | c.7786T>C p.S2596P | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2
- PIGN | c.2368C>T p.L790F | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PJA2 | c.1120A>T p.M374L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PKP2 | c.1867C>G p.P623A | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLXNB3 | c.1363G>C p.G455R | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- PLXNB3 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- POGZ | c.2141A>T p.E714V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- POLE | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLI | c.457A>C p.N153H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- POM121L2 | c.1241C>A p.S414Y | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by mutect2, varscan2
- POTEH | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); called by muse, mutect2
- PPP1R15A | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2
- PPP4R4 | c.2257G>C p.G753R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PPP6R3 | c.405del p.K135Nfs*9 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- PRKCG | c.1850T>C p.I617T | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PRKDC | c.11108-7G>T | Splice Region (SNP) | VAF 60/113 reads (53%) | called by muse, mutect2, varscan2
- PRKG1 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTGER4P2 | n.55-1G>A | Splice Site (SNP) | VAF 18/167 reads (11%) | called by muse, varscan2
- PTPN4 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.065); called by muse, mutect2
- RALGAPB | c.622A>T p.T208S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RDH11 | c.272A>T p.N91I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- REG1B | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RFPL4A | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- RFX2 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RGS4 | c.322A>C p.S108R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RNF111 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNPEPL1 | c.487T>A p.F163I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ROBO2 | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, varscan2
- RTN1 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RTTN | c.5029C>T p.Q1677* | Nonsense Mutation (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- SALL3 | c.2018A>G p.K673R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); called by muse, varscan2
- SEC22C | c.902G>T p.C301F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SENP3 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- SEPTIN4 | c.907C>G p.P303A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SH2D7 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2
- SIDT2 | c.1051A>C p.S351R | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIGLEC5 | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- SIGLEC6 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SLC17A8 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC19A1 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SLC26A8 | c.945T>G p.I315M | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- SLC2A10 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SMARCA1 | c.3073A>T p.K1025* | Nonsense Mutation (SNP) | VAF 42/70 reads (60%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.64A>T p.R22* | Nonsense Mutation (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- TACC2 | c.7609-2A>T p.X2537_splice (on ENST00000334433; = p.X615_splice on NM_006997.4) | Splice Site (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2
- TBX19 | c.1129A>T p.T377S | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- TERT | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TESPA1 | c.460C>A p.L154M (on ENST00000316577 / NM_001098815.3; = p.L16M on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX15 | c.6967C>G p.Q2323E (on ENST00000256246; = p.Q2706E on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TIAM2 | c.3420G>T p.M1140I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TIMM23 | c.620A>C p.Q207P | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TMEM132C | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM178B | c.247C>G p.R83G | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by mutect2, varscan2
- TMEM67 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2
- TMEM94 | c.3042G>C p.Q1014H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRANK1 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2
- TRAV6 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | called by muse, varscan2
- TREML2 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, varscan2
- TREX2 | c.-820-1G>T | Splice Site (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- TRIM7 | c.1341C>G p.S447R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- TVP23A | c.345_347del p.A116del | In Frame Del (DEL) | VAF 12/70 reads (17%) | called by pindel, varscan2
- UBR2 | c.2893A>C p.N965H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- UCHL5 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- XKR9 | c.52T>C p.Y18H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.5645G>A p.G1882D | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZFYVE26 | c.2756G>T p.G919V | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMYND11 | c.134A>G p.H45R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ZNF514 | c.689A>T p.K230M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF777 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZNF81 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ABCC2 | c.2409C>A p.V803= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- ADAM11 | c.666A>G p.R222= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.5451G>C p.T1817= | Silent (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- AGK | c.48A>T p.T16= | Silent (SNP) | VAF 20/154 reads (13%) | called by muse, varscan2
- ALCAM | c.1635C>T p.V545= | Silent (SNP) | VAF 49/237 reads (21%) | catalogued as rs199833756; called by muse, mutect2, varscan2
- ASPSCR1 | c.189C>A p.L63= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- ASXL3 | c.972A>T p.A324= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- ATP1B4 | c.243C>T p.A81= | Silent (SNP) | VAF 115/175 reads (66%) | called by muse, mutect2, varscan2
- ATP7A | c.1722G>T p.T574= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs207478437; called by muse, mutect2, varscan2
- AXDND1 | c.2316A>T p.A772= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- BOD1L1 | c.3537A>G p.P1179= | Silent (SNP) | VAF 18/126 reads (14%) | called by muse, varscan2
- C10orf90 | c.336G>T p.P112= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99504635; called by muse, mutect2, varscan2
- C11orf95 | c.1833G>T p.T611= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100379995; called by muse, mutect2, varscan2
- C1QL3 | c.186C>A p.P62= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- CACNA1E | c.5475T>C p.G1825= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- CDH18 | c.2271G>A p.T757= | Silent (SNP) | VAF 16/238 reads (7%) | catalogued as rs370593800, COSV99932797; called by muse, mutect2
- CHD7 | c.8010C>G p.P2670= | Silent (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- COL16A1 | c.1746C>T p.G582= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- COL1A2 | c.3915C>T p.N1305= | Silent (SNP) | VAF 34/185 reads (18%) | called by muse, mutect2, varscan2
- COL20A1 | c.1416G>T p.A472= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV58911130, COSV58927522; called by muse, mutect2, varscan2
- COL20A1 | c.3084C>A p.L1028= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- COL6A3 | c.3006T>A p.I1002= | Silent (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- COL9A2 | c.1962G>T p.L654= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs142867960; ClinVar: likely benign; called by mutect2, varscan2
- COPA | c.438A>G p.T146= | Silent (SNP) | VAF 51/184 reads (28%) | catalogued as rs1175575867; called by muse, mutect2, varscan2
- CPLANE1 | c.7873C>T p.L2625= | Silent (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- CROCC2 | c.2301G>T p.L767= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV70369584; called by muse, mutect2, varscan2
- CRYBB3 | c.495C>G p.G165= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- DHRS9 | c.171C>T p.I57= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs754346896, COSV59138981; called by muse, mutect2, varscan2
- DNAH6 | c.1368G>A p.T456= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs372969433; called by muse, mutect2, varscan2
- DSG4 | c.1767C>T p.C589= | Silent (SNP) | VAF 28/210 reads (13%) | catalogued as rs774893070, COSV100355848; called by muse, mutect2, varscan2
- ECM2 | c.1350C>T p.L450= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- FAM110B | c.240G>T p.L80= | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- FAM117B | c.810C>T p.R270= | Silent (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- FAM172A | c.337C>T p.L113= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1284237971, COSV67936917; called by muse, mutect2, varscan2
- GAPDH | c.255C>A p.I85= | Silent (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- GCNT4 | c.1257C>A p.I419= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV59280506; called by muse, mutect2, varscan2
- GFRAL | c.810A>T p.S270= | Silent (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- GJD2 | c.756C>A p.V252= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV51748655; called by muse, mutect2, varscan2
- GNB2 | c.436C>T p.L146= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- GRIA4 | c.426C>A p.L142= | Silent (SNP) | VAF 36/213 reads (17%) | called by muse, mutect2, varscan2
- GSTA1 | c.579A>G p.T193= | Silent (SNP) | VAF 21/258 reads (8%) | catalogued as rs552982129, COSV58016985; called by muse, mutect2
- HEPH | c.1389G>A p.E463= (on ENST00000343002; = p.E196= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs948357514; called by muse, mutect2, varscan2
- IGHV3-35 | c.327C>T p.D109= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, varscan2
- KANSL1 | c.825C>T p.F275= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- KRT39 | c.207C>T p.P69= | Silent (SNP) | VAF 37/122 reads (30%) | called by muse, mutect2, varscan2
- LAMA3 | c.3996G>C p.T1332= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV58072081; called by muse, mutect2, varscan2
- LMX1B | c.768G>T p.T256= | Silent (SNP) | VAF 62/184 reads (34%) | catalogued as COSV62740777; called by muse, mutect2, varscan2
- LYZL6 | c.270G>T p.S90= | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- MDGA2 | c.2697C>A p.P899= (on ENST00000399232 / NM_001113498.2; = p.P601= on NM_182830.4) | Silent (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- MFSD5 | c.840T>A p.P280= | Silent (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- MYO9A | c.5689C>T p.L1897= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- NRXN1 | c.465C>T p.V155= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs531571569, COSV68004656; called by muse, mutect2, varscan2
- OAS3 | c.1197C>A p.P399= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- OR5M11 | c.498C>A p.T166= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- OR5M8 | c.717C>A p.T239= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- OR5T1 | c.714G>T p.L238= | Silent (SNP) | VAF 42/146 reads (29%) | called by muse, varscan2
- PCDH19 | c.2718T>C p.D906= (on ENST00000373034 / NM_001184880.2; = p.D858= on NM_020766.3) | Silent (SNP) | VAF 75/140 reads (54%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1341C>T p.N447= | Silent (SNP) | VAF 36/196 reads (18%) | catalogued as rs1459171550, COSV53376231; called by muse, mutect2, varscan2
- POLD2 | c.279G>C p.V93= | Silent (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- POM121L2 | c.1566T>A p.S522= | Silent (SNP) | VAF 25/208 reads (12%) | called by muse, mutect2, varscan2
- PRKDC | c.8640C>T p.C2880= | Silent (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- PRR12 | c.2217G>A p.E739= (on ENST00000615927; = p.E1560= on NM_020719.3) | Silent (SNP) | VAF 54/165 reads (33%) | catalogued as rs1365960215; called by muse, mutect2, varscan2
- PSG4 | c.9C>A p.P3= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV54940639; called by muse, mutect2
- PTAFR | c.111G>T p.L37= | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- PTPRT | c.2584C>A p.R862= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV61978956; called by muse, mutect2, varscan2
- RBM18 | c.39A>G p.A13= | Silent (SNP) | VAF 51/223 reads (23%) | catalogued as rs1252552951; called by muse, mutect2, varscan2
- RBM46 | c.1317C>A p.S439= | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- RIN3 | c.2922G>T p.P974= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs767719783; called by muse, mutect2, varscan2
- SLC12A1 | c.3279T>C p.N1093= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs1457524915; called by muse, mutect2, varscan2
- SLC22A6 | c.168C>T p.N56= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV100842877; called by muse, mutect2, varscan2
- SLC4A10 | c.1245A>G p.S415= (on ENST00000446997 / NM_001354461.2; = p.S385= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- SLC6A18 | c.456C>T p.C152= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- SOX7 | c.102G>C p.R34= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- SP8 | c.1401G>C p.A467= (on ENST00000361443 / NM_198956.4; = p.A485= on NM_182700.6) | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- STON2 | c.2214T>C p.F738= (on ENST00000649389 / NM_001366849.2; = p.F681= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- TBX21 | c.123C>A p.G41= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as rs1380933175; called by muse, mutect2, varscan2
- TDRD6 | c.2496G>A p.Q832= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- TENM2 | c.39A>G p.R13= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as rs1235511898; called by muse, mutect2, varscan2
- TENM2 | c.5424C>T p.I1808= (on ENST00000518659 / NM_001122679.2; = p.I1569= on NM_001080428.3) | Silent (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- TIMP4 | c.288T>G p.P96= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- TRIM58 | c.1335G>T p.R445= | Silent (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- TUBA3C | c.345C>A p.V115= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs552346334, COSV67139732; called by muse, mutect2, varscan2
- ULK1 | c.1713C>T p.P571= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- UNC13B | c.726T>C p.S242= | Silent (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- VPS13D | c.11712C>T p.I3904= | Silent (SNP) | VAF 48/194 reads (25%) | catalogued as rs202027166; called by muse, varscan2
- YME1L1 | c.231C>T p.F77= | Silent (SNP) | VAF 37/202 reads (18%) | catalogued as rs753921603, COSV58759340; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2574G>C p.T858= | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- ZDHHC14 | c.1125G>T p.T375= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- ZNF441 | c.1026G>A p.G342= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- ZNF462 | c.1467A>G p.K489= | Silent (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- ABLIM1 | c.-11G>C | 5'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- AKR1B15 | c.150+715G>T | Intron (SNP) | VAF 43/149 reads (29%) | called by muse, mutect2, varscan2
- ALKBH4 | c.-1G>T | 5'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.*1336T>C | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- BBS2 | c.1528-127A>T | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- C15orf40 | chr15:82988711 G>T | 3'Flank (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- C4orf50 | c.-1022del | 5'UTR (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- CALM3 | c.3+728C>G | Intron (SNP) | VAF 63/225 reads (28%) | called by muse, mutect2, varscan2
- CHD9 | c.7713+1503G>T | Intron (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- CIB2 | c.198+463T>C | Intron (SNP) | VAF 7/158 reads (4%) | called by muse, mutect2
- COL3A1 | c.282+26C>A | Intron (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- CREB5 | chr7:28410189 G>A | 5'Flank (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- DPF3 | c.871+3101C>T | Intron (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- DPP6 | c.457+39del | Intron (DEL) | VAF 31/193 reads (16%) | called by mutect2, pindel, varscan2
- EGFR | c.1881-601del | Intron (DEL) | VAF 17/104 reads (16%) | catalogued as COSV99292629; called by mutect2, varscan2
- ENTPD2 | c.1150-177G>T | Intron (SNP) | VAF 34/129 reads (26%) | catalogued as COSV57076116; called by muse, mutect2, varscan2
- EPCAM | c.76+149C>T | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs1482428245; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11547C>G | Intron (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- GOLGA6L17P | n.548A>T | RNA (SNP) | VAF 106/501 reads (21%) | called by muse, varscan2
- GRIK1 | c.1794-804C>A | Intron (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- GSTM4 | chr1:109665057 C>A | 3'Flank (SNP) | VAF 14/138 reads (10%) | called by muse, varscan2
- HMGN1 | c.78+22A>G | Intron (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- HMGN5 | c.-14A>T | 5'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-16536C>A | Intron (SNP) | VAF 58/145 reads (40%) | called by muse, mutect2, varscan2
- LYPD3 | c.382+63G>T | Intron (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85548G>T | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as COSV72280098, COSV72282613; called by muse, varscan2
- MC2R | c.-50C>A | 5'UTR (SNP) | VAF 20/82 reads (24%) | catalogued as COSV59617670, COSV59617684; called by muse, varscan2
- MIR509-1 | n.27G>T | RNA (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- MYO1F | c.3+19G>A | Intron (SNP) | VAF 47/90 reads (52%) | catalogued as rs1555734028; called by muse, mutect2, varscan2
- NCAM1 | c.1826-5588C>A | Intron (SNP) | VAF 28/190 reads (15%) | called by muse, mutect2, varscan2
- NFATC4 | chr14:24367211 C>A | 5'Flank (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99151197; called by muse, mutect2, varscan2
- NUP214 | c.*40C>T | 3'UTR (SNP) | VAF 46/181 reads (25%) | catalogued as COSV100845083; called by muse, varscan2
- PCID2 | c.-6G>T | 5'UTR (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- PDIA3P1 | n.1421A>G | RNA (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- PPY2P | n.585C>A | RNA (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- PRSS40A | n.317+91G>T | Intron (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2, varscan2
- PTGDR | c.846+800C>A | Intron (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- RBKS | c.-5G>C | 5'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100141852; called by muse, mutect2, varscan2
- SNX24 | c.249+19318C>A | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, varscan2
- SPI1 | c.-14C>T | 5'UTR (SNP) | VAF 16/63 reads (25%) | catalogued as rs200729695; called by muse, mutect2, varscan2
- SPTBN1 | c.148+3053G>T | Intron (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- TAFA5 | c.263-14342T>A | Intron (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- TBC1D29P | n.2666G>A | RNA (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- TEX35 | chr1:178525407 C>G | 3'Flank (SNP) | VAF 19/148 reads (13%) | called by muse, varscan2
- TMEM135 | c.*36C>T | 3'UTR (SNP) | VAF 29/179 reads (16%) | called by muse, mutect2, varscan2
- TMEM236 | c.*2058T>A | 3'UTR (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- TRIM11 | c.859+257C>T | Intron (SNP) | VAF 7/28 reads (25%) | catalogued as rs901363270; called by muse, varscan2
- TTC41P | n.246A>T | RNA (SNP) | VAF 42/120 reads (35%) | catalogued as rs1000788395; called by muse, mutect2, varscan2
- UBE2DNL | n.134G>A | RNA (SNP) | VAF 3/25 reads (12%) | called by muse, varscan2
- UGT1A1 | c.1304+1120T>C | Intron (SNP) | VAF 34/110 reads (31%) | called by muse, varscan2
- XKR6 | c.764+76682A>T | Intron (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149776462 A>G | 5'Flank (SNP) | VAF 13/64 reads (20%) | catalogued as rs774923570; called by muse, mutect2, varscan2
